Somatic mutation profile of tumor specimen 0E1O0G from CCDI case PBCWNL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1O0G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79b8900c-06d2-43a7-8a1a-39985b8803b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1NYS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c335f0b-9055-47bc-a47f-d4683b7fd2d0

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHAT | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 26/577 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs141111059, CM158438; called by muse, mutect2
- PCDHAC1 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs781857799, COSV53846278; called by muse, mutect2
- CROT | c.1695T>A p.F565L | Missense Mutation (SNP) | VAF 65/343 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- EVC2 | c.2185G>A p.D729N | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PCDHB11 | c.2034G>A p.P678= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs1554285710, COSV61310913; called by muse, mutect2, varscan2
